Somatic mutation profile of tumor specimen TCGA-CN-A63Y-01A (aliquot TCGA-CN-A63Y-01A-11D-A30E-08) from TCGA case TCGA-CN-A63Y, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 46.9 years (17,125 days).
Specimen TCGA-CN-A63Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bad9b04-4385-421a-a7e0-dd446ca00d45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A63Y-10A (Blood Derived Normal), aliquot TCGA-CN-A63Y-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fa7e384-d5d1-487e-ab61-b0997d8d5f8e

The open-access MAF lists 180 somatic variants for this specimen: 121 protein-altering or splice-affecting, 52 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 52, Nonsense Mutation 13, RNA 3, Intron 3, Frame Shift Del 2, Splice Site 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PSG4 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 68/332 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV54932991; called by muse, mutect2
- ABL2 | c.1363G>C p.E455Q (on ENST00000502732 / NM_007314.4; = p.E440Q on NM_005158.5) | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61020180; called by muse, mutect2, varscan2
- ADAMTS10 | c.1512G>C p.K504N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99547353; called by muse, mutect2
- ADAMTS6 | c.2752G>C p.G918R | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100068571; called by muse, mutect2, varscan2
- ARHGAP15 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1177528659, COSV99707629; called by muse, mutect2, varscan2
- ATF4 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as COSV100307813, COSV57477799; called by muse, mutect2, varscan2
- ATP2A1 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100837385; called by muse, mutect2, varscan2
- ATP2B2 | c.1002G>C p.Q334H (on ENST00000352432; = p.Q345H on NM_001001331.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as COSV100660400; called by muse, mutect2, varscan2
- BAG2 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100443867; called by muse, mutect2, varscan2
- BMT2 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV99774815; called by muse, mutect2, varscan2
- BSND | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100987658; called by muse, mutect2, varscan2
- CCN3 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99423274; called by muse, mutect2, varscan2
- CENPF | c.3493G>C p.E1165Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs368660042, COSV100871924; called by muse, mutect2, varscan2
- CEP350 | c.8542G>A p.E2848K | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100855134; called by muse, mutect2
- CGB5 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100032110; called by mutect2, varscan2
- CHFR | c.799G>C p.D267H (on ENST00000432561 / NM_001161345.1; = p.D226H on NM_018223.2) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV57177071, COSV99905672; called by muse, mutect2, varscan2
- CMYA5 | c.2373C>G p.F791L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV101484305; called by muse, mutect2, varscan2
- CNGA3 | c.981del p.F327Lfs*35 | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | catalogued as COSV55623409; called by mutect2, pindel, varscan2
- CNTNAP1 | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99226912; called by muse, mutect2, varscan2
- COL22A1 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV100280475; called by muse, mutect2, varscan2
- COL6A6 | c.3818C>A p.P1273Q | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62021548; called by muse, mutect2, varscan2
- CSNK2A1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99424673; called by muse, mutect2, varscan2
- DCAF12 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100778402; called by muse, mutect2, varscan2
- DEAF1 | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100102315; called by muse, mutect2, varscan2
- DEFB136 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV101198626; called by muse, mutect2, varscan2
- DNASE1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs371345873; called by muse, mutect2, varscan2
- DSN1 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV101041104; called by muse, mutect2, varscan2
- DZIP1 | c.1801C>G p.Q601E (on ENST00000347108; = p.Q582E on NM_014934.5) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100714173; called by muse, mutect2, varscan2
- ENOX1 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99816956; called by muse, mutect2, varscan2
- EPHB4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100639628; called by muse, mutect2, varscan2
- EXOC6B | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV99726109; called by muse, mutect2, varscan2
- FAM209A | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as COSV99711691; called by muse, mutect2, varscan2
- FANCD2 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as COSV99812287; called by muse, mutect2, varscan2
- FANCD2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV99812289; called by muse, mutect2, varscan2
- FCGR1A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs782812046, COSV100977254; called by muse, mutect2, varscan2
- FOXG1 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); catalogued as COSV100487033; called by muse, mutect2, varscan2
- FREM2 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs764017977, COSV54839160; called by muse, mutect2, varscan2
- GFM2 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV99714653; called by muse, mutect2, varscan2
- GPX1 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101346325; called by muse, mutect2, varscan2
- GRIP1 | c.1790G>A p.G597E (on ENST00000359742 / NM_001379345.1; = p.G545E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99670759; called by muse, mutect2, varscan2
- GUCY1A1 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV99638471; called by muse, mutect2, varscan2
- H2AC21 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100480058, COSV58613229; called by muse, mutect2, varscan2
- HHAT | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as rs113371678, COSV99801954; called by muse, mutect2, varscan2
- HLA-B | c.620-1G>A p.X207_splice | Splice Site (SNP) | VAF 38/199 reads (19%) | catalogued as COSV69520348, COSV69521615; called by muse, mutect2, varscan2
- HNF4A | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs768495780, COSV100291698, COSV57383521; called by muse, mutect2, varscan2
- HOXA13 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56084013; called by muse, mutect2, varscan2
- HPD | c.1113C>G p.F371L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100000203; called by muse, mutect2, varscan2
- HUWE1 | c.13109G>A p.G4370D | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99473957; called by muse, mutect2
- KIAA0586 | c.2038A>C p.T680P (on ENST00000619416 / NM_001244190.2; = p.T619P on NM_014749.5) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99708769; called by muse, mutect2, varscan2
- KLHL1 | c.990G>A p.M330I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV100918030, COSV64786204; called by muse, mutect2, varscan2
- KMT2C | c.13080G>A p.W4360* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV51414452; called by muse, mutect2, varscan2
- LACRT | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.112); catalogued as rs1470414707, COSV99143901; called by muse, mutect2, varscan2
- LIMS1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs768178569, COSV100186038; called by muse, mutect2, varscan2
- LRRN1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs377314657; called by muse, mutect2, varscan2
- MORN5 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055646; called by muse, mutect2, varscan2
- MRTFB | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371750; called by muse, mutect2, varscan2
- MYO9A | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614193; called by muse, mutect2, varscan2
- NAA15 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as CD135251, COSV56717517; called by muse, mutect2, varscan2
- NADK | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 63/280 reads (23%) | catalogued as COSV100411031; called by muse, mutect2, varscan2
- NAPG | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100529891; called by muse, mutect2
- NDEL1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs764427521, COSV100233231; called by muse, mutect2, varscan2
- NDST4 | c.2425C>T p.Q809* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99997662; called by muse, mutect2, varscan2
- NKD2 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.906); catalogued as COSV99724360; called by muse, mutect2, varscan2
- NR1H2 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99516515; called by muse, mutect2, varscan2
- NTNG2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs887475720, COSV100647333, COSV62368208; called by muse, mutect2, varscan2
- NXPH1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs773388495, COSV101339789, COSV68311055; called by muse, mutect2, varscan2
- OOEP | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.083); catalogued as COSV100949861; called by muse, mutect2, varscan2
- OR2M7 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV58740180; called by muse, mutect2, varscan2
- OSBPL6 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs963803569, COSV99508385; called by muse, mutect2
- PARP14 | c.4496G>A p.G1499E | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101506339; called by muse, mutect2, varscan2
- PARP8 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99892581; called by muse, mutect2, varscan2
- PCDHA1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); catalogued as rs782199797, COSV65372985; called by muse, mutect2, varscan2
- PCDHA7 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV65342235, COSV65347101; called by muse, mutect2, varscan2
- PCSK5 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs755978345, COSV70450087; called by muse, mutect2
- PCSK6 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as COSV100624413; called by muse, mutect2, varscan2
- PLEKHB2 | c.571C>T p.R191* (on ENST00000409279; = p.R190* on NM_017958.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/287 reads (22%) | catalogued as rs376927744; called by muse, mutect2, varscan2
- PLPPR5 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99587816; called by muse, mutect2, varscan2
- PNMA5 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100721701; called by muse, mutect2, varscan2
- PPFIA3 | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100495211, COSV61954612; called by muse, mutect2, varscan2
- PRRG1 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101069106; called by muse, mutect2, varscan2
- PSG4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV99737726; called by muse, mutect2, varscan2
- PSG4 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99737728; called by muse, mutect2, varscan2
- RARG | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as COSV100553658; called by muse, mutect2, varscan2
- RERGL | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99968046; called by muse, mutect2, varscan2
- RIC8A | c.970-1G>A p.X324_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100291553; called by muse, mutect2, varscan2
- RNF144A | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV100306049; called by muse, mutect2, varscan2
- RTL4 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | catalogued as rs139116920, COSV100465786, COSV61207359; called by muse, mutect2, varscan2
- SAMD14 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.884); catalogued as rs1488483370, COSV53309365, COSV99557573; called by muse, varscan2
- SCG3 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs775852158, COSV55020878; called by muse, mutect2, varscan2
- SCN9A | c.5410G>A p.D1804N (on ENST00000303354; = p.D1793N on NM_002977.3) | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV57610548; called by muse, mutect2, varscan2
- SCN9A | c.4865G>A p.R1622H (on ENST00000303354; = p.R1611H on NM_002977.3) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1346697903, COSV100312512; called by muse, mutect2, varscan2
- SERPINA6 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs1085307658, COSV100448446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A36 | c.772G>T p.G258* (on ENST00000324194 / NM_001104647.3; = p.G257* on NM_018155.3) | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100149207; called by muse, mutect2, varscan2
- SMO | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99977045; called by muse, mutect2, varscan2
- SPAG5 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV58803606; called by muse, mutect2, varscan2
- SPINT2 | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100007663; called by muse, mutect2, varscan2
- SRP54 | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99392805; called by muse, mutect2, varscan2
- SRRM2 | c.5383C>T p.Q1795* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100071371; called by muse, mutect2, varscan2
- STXBP5L | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV99876111; called by muse, mutect2, varscan2
- STXBP5L | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.32); catalogued as COSV99876112; called by muse, mutect2, varscan2
- TLE1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as rs556195256, COSV64689876; called by muse, mutect2, varscan2
- TMEM168 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV100454765; called by muse, mutect2, varscan2
- TMEM215 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV61363346; called by muse, mutect2, varscan2
- TNFRSF9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs145966863; called by muse, mutect2, varscan2
- TOM1L2 | c.695G>A p.R232Q (on ENST00000379504 / NM_001350333.2; = p.R182Q on NM_001033551.3) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1480281935, COSV100541203; called by muse, mutect2, varscan2
- TRIM36 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as rs765467230, COSV56689962, COSV99142510; called by muse, mutect2, varscan2
- TUBGCP4 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99539377, COSV99539453; called by muse, mutect2, varscan2
- TUBGCP6 | c.2268G>A p.A756= | Splice Region (SNP) | VAF 10/60 reads (17%) | catalogued as rs368982253; called by muse, mutect2, varscan2
- UGT3A1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1317305154, COSV57096698; called by muse, mutect2, varscan2
- USP34 | c.9299A>G p.K3100R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as COSV101277183; called by muse, mutect2, varscan2
- WDFY3 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99885342; called by muse, mutect2, varscan2
- ZBTB26 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV101021152; called by muse, mutect2
- ZNF131 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100185692; called by muse, mutect2, varscan2
- ZNF43 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100731933, COSV61682855, COSV61684299; called by muse, mutect2, varscan2
- ZNF562 | c.394G>A p.E132K (on ENST00000453372 / NM_001130032.2; = p.E60K on NM_017656.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV99530843; called by muse, mutect2, varscan2
- ZNRD2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100326109; called by muse, mutect2, varscan2
- MAGEC1 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- MON1A | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF750 | c.606_607del p.P203Wfs*18 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- ANLN | c.2331G>A p.L777= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99732770; called by muse, mutect2, varscan2
- BYSL | c.477G>A p.Q159= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100026930; called by muse, mutect2, varscan2
- C3AR1 | c.384C>T p.I128= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99368905; called by muse, mutect2, varscan2
- CACNA1A | c.5109G>A p.L1703= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs757461090, COSV100803099, COSV64215827; called by muse, varscan2
- CDH4 | c.1941C>T p.Y647= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as rs777327873, COSV64645345, COSV64665328; called by muse, mutect2, varscan2
- CLCN7 | c.1431C>T p.L477= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99247568; called by muse, varscan2
- COG4 | c.159C>G p.L53= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs753679808, COSV100092251; called by muse, mutect2, varscan2
- DCBLD1 | c.1596C>T p.L532= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs1440598873, COSV99758019; called by muse, mutect2, varscan2
- DNAH3 | c.10011G>A p.T3337= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as rs367808003; called by muse, mutect2, varscan2
- DOP1B | c.2343G>A p.Q781= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV101215132; called by muse, mutect2, varscan2
- DUSP19 | c.579C>T p.F193= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV100700206; called by muse, mutect2, varscan2
- FANCD2 | c.969G>A p.L323= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99812283; called by muse, mutect2, varscan2
- FERD3L | c.354C>T p.N118= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV51764456; called by muse, mutect2, varscan2
- FGFR1OP2 | c.579C>T p.D193= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs749794108, COSV99987025; called by muse, mutect2, varscan2
- GABRB2 | c.132G>A p.L44= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99196251, COSV99196530; called by muse, mutect2, varscan2
- GAPDH | c.438C>A p.I146= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99975655; called by muse, mutect2, varscan2
- GPR55 | c.753G>A p.L251= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV101235920; called by muse, mutect2, varscan2
- HIPK3 | c.519G>A p.Q173= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100306023; called by muse, mutect2, varscan2
- HPS4 | c.1056C>T p.L352= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV61106104; called by muse, mutect2, varscan2
- HTR3C | c.1230G>A p.Q410= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100570733; called by muse, mutect2, varscan2
- IGKV3D-11 | c.285C>A p.I95= | Silent (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- IPO5 | c.1485G>A p.L495= | Silent (SNP) | VAF 26/228 reads (11%) | catalogued as rs1175383861, COSV99847603; called by muse, mutect2
- KIF21A | c.1008C>T p.L336= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs771660427, COSV62766989, COSV62776699; called by muse, mutect2, varscan2
- KNTC1 | c.4518G>A p.T1506= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs764898553, COSV100338724; called by muse, mutect2, varscan2
- MON1A | c.888C>T p.I296= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99616978; called by muse, mutect2, varscan2
- NEB | c.5052C>T p.F1684= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs755060324, COSV99427168; called by muse, varscan2
- NF1 | c.2640G>A p.V880= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as rs786202443, COSV100648110; ClinVar: likely benign; called by muse, mutect2, varscan2
- NSD2 | c.1779A>G p.A593= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs755333913, COSV100373814; called by muse, mutect2, varscan2
- NUDT16 | c.117C>T p.I39= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100720830; called by muse, mutect2, varscan2
- OR9A2 | c.90C>T p.F30= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs747172605, COSV100628281; called by muse, mutect2, varscan2
- ORAI2 | c.639C>G p.V213= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100709964; called by muse, mutect2, varscan2
- PCDHA3 | c.1611G>A p.A537= | Silent (SNP) | VAF 57/253 reads (23%) | catalogued as COSV63539318; called by muse, mutect2, varscan2
- PHF3 | c.3621C>T p.F1207= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs769036130, COSV100013842; called by muse, mutect2, varscan2
- POSTN | c.798C>T p.D266= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs759253817, COSV101123470, COSV65712939; called by muse, mutect2, varscan2
- PRPF8 | c.5490G>A p.Q1830= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100517838; called by muse, mutect2, varscan2
- RHPN2 | c.1605C>T p.P535= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs778168443, COSV99578200; called by muse, mutect2, varscan2
- SHMT2 | c.789G>A p.V263= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs900833068, COSV100197360; called by muse, mutect2, varscan2
- SKA3 | c.501C>T p.I167= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as rs557088655, COSV53435764; called by muse, mutect2, varscan2
- SLC32A1 | c.684C>T p.L228= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99462592; called by muse, mutect2, varscan2
- SLC35E3 | c.396C>T p.L132= | Silent (SNP) | VAF 32/163 reads (20%) | catalogued as COSV99972000; called by muse, mutect2, varscan2
- SLC4A2 | c.3477G>A p.R1159= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99879947; called by muse, varscan2
- STEAP2 | c.963C>G p.L321= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99840209, COSV99840665; called by muse, mutect2, varscan2
- TAS1R2 | c.1209C>T p.L403= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs746134843, COSV100946344; called by muse, mutect2
- TBC1D24 | c.1629C>T p.F543= (on ENST00000646147 / NM_001199107.2; = p.F537= on NM_020705.3) | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99565252; called by muse, mutect2
- TBL1Y | c.846G>A p.L282= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100667345; called by muse, mutect2, varscan2
- TLR5 | c.654A>G p.K218= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV100643371; called by muse, mutect2, varscan2
- TTF2 | c.1158C>T p.F386= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101037805; called by muse, mutect2, varscan2
- VPS13B | c.4638G>A p.L1546= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100663325; called by muse, mutect2, varscan2
- ZFHX3 | c.5067G>A p.G1689= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV99214402; called by muse, mutect2, varscan2
- ZNF521 | c.3213C>G p.L1071= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV64131145; called by muse, mutect2, varscan2
- ZNF609 | c.3027G>A p.Q1009= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as rs1168501443, COSV100441702; called by muse, mutect2, varscan2
- ZSCAN5B | c.246G>A p.Q82= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100748530, COSV100748536; called by muse, mutect2, varscan2
- AC024940.1 | n.3053C>T | RNA (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- GAS8 | c.90+1491C>T | Intron (SNP) | VAF 16/63 reads (25%) | catalogued as rs554912454, COSV99244172; called by muse, mutect2
- GLOD4 | chr17:783120 G>A | 5'Flank (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100022583; called by muse, mutect2, varscan2
- LDB3 | c.896+6723G>A | Intron (SNP) | VAF 49/239 reads (21%) | catalogued as rs868365512, COSV53947723, COSV99555819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINC01588 | n.879C>T | RNA (SNP) | VAF 39/223 reads (17%) | catalogued as rs200836841; called by muse, mutect2, varscan2
- RNF216 | c.202-52G>C | Intron (SNP) | VAF 41/199 reads (21%) | catalogued as COSV101111377; called by muse, mutect2, varscan2
- TP73-AS1 | n.1139C>T | RNA (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
